Gene-level copy-number profile of tumor specimen ALCH-AD0F-TTP1-A from ALCHEMIST case ALCH-AD0F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 63.9 years (23,330 days).
Specimen ALCH-AD0F-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 281d1e6a-76c8-4813-b793-1282b59c70a3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AD0F-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/0bb47877-82bc-41d8-a0d0-f015eab653a2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 20,577; copy number 2: 36,798; copy number 3: 674; copy number 4: 115; copy number 5: 114; copy number 6: 254; copy number 7: 68; copy number 8: 144; copy number 9: 8; copy number 10: 7; copy number 12: 18; copy number 32: 1.

Homozygous deletions (total copy number 0; autosomes only): 121 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,272,393–25,330,445, 2 genes (within-gene range 0–2): RHD, SDHDP6.
- chr2:72,932,974–72,934,355, 1 gene (within-gene range 0–2): AC012366.1.
- chr2:130,830,978–130,836,994, 1 gene (within-gene range 0–1): AC133785.1.
- chr5:177,400,109–177,400,661, 1 gene: PFN3.
- chr6:168,242,938–168,262,581, 1 gene: AL606970.3.
- chr7:128,830,406–128,862,626, 2 genes (within-gene range 0–1): FLNC, FLNC-AS1.
- chr7:149,262,171–149,297,312, 3 genes: ZNF783, AC004890.3, AC004890.2.
- chr8:22,613,908–22,616,657, 1 gene (within-gene range 0–2): AC037459.2.
- chr10:49,771,841–49,773,299, 1 gene: MAPK6P6.
- chr10:78,068,623–78,069,538, 1 gene: GNAI2P2.
- chr12:121,777,754–121,803,403, 1 gene (within-gene range 0–1): RHOF.
- chr13:19,126,399–19,187,618, 6 genes: CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1.
- chr15:25,169,337–25,257,027, 46 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:41,825,099–41,899,528, 8 genes (within-gene range 0–1): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310, AC020659.1.
- chr15:64,151,715–64,163,022, 2 genes: SNX22, PPIB.
- chr15:68,296,532–68,432,163, 1 gene: ITGA11.
- chr15:73,319,859–73,368,958, 2 genes: HCN4, AC068397.2.
- chr15:85,750,336–85,756,237, 2 genes: AC021739.4, LINC02883.
- chr15:85,770,496–85,771,163, 2 genes (within-gene range 0–1): MIR1276, AC021739.1.
- chr15:90,839,641–90,895,776, 4 genes: AC124248.1, RN7SL363P, FURIN, FES.
- chr16:2,204,248–2,235,742, 5 genes (within-gene range 0–2): MLST8, BRICD5, PGP, AC009065.7, E4F1.
- chr16:50,606,076–50,613,684, 1 gene (within-gene range 0–2): AC007608.1.
- chr16:86,510,527–86,515,422, 1 gene: FOXF1.
- chr17:16,427,474–16,428,719, 1 gene (within-gene range 0–1): AC093484.1.
- chr17:38,450,394–38,452,444, 1 gene (within-gene range 0–2): AC244153.1.
- chr17:48,958,554–48,968,596, 1 gene: GIP.
- chr17:50,346,126–50,365,232, 2 genes: XYLT2, AC015909.5.
- chr17:61,452,404–61,485,110, 2 genes: TBX4, AC005901.1.
- chr17:62,626,031–62,693,597, 6 genes (within-gene range 0–2): AC080038.2, AC080038.1, MRC2, Y_RNA, AC080038.3, RNU6-446P.
- chr17:82,371,400–82,418,637, 5 genes (within-gene range 0–1): UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA.
- chr20:43,667,019–43,716,495, 1 gene: MYBL2.
- chr22:19,045,256–19,056,512, 3 genes (within-gene range 0–1): Y_RNA, DGCR11, AC004461.1.
- chr22:23,762,990–23,767,972, 2 genes: C22orf15, CHCHD10.
- chr22:23,856,427–23,857,039, 1 gene (within-gene range 0–2): AP000350.5.
- chr22:36,286,847–36,286,907, 1 gene (within-gene range 0–2): MIR6819.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 613 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 7: RPL23AP88.
- chr5:58,198–24,910,695, 390 genes, copy number 5–12 (broad region; genes not listed).
- chr5:35,852,695–37,753,435, 38 genes, copy number 5: IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P.
- chr11:1,947,278–1,984,522, 1 gene, copy number 32 (within-gene range 3–32): MRPL23.
- chr20:52,858,338–62,700,480, 183 genes, copy number 5–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,735. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
